Gene-level copy-number profile of tumor specimen TCGA-AJ-A23N-01A from TCGA case TCGA-AJ-A23N, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 70.6 years (25,772 days).
Specimen TCGA-AJ-A23N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.f488f0b0-ec7e-4899-a771-86c0f98c79c6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A23N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/79a0c9dc-2efe-4ee0-832f-e8d8911d8591

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 800; copy number 2: 14,139; copy number 3: 20,977; copy number 4: 15,379; copy number 5: 2,407; copy number 6: 4,438; copy number 7: 962; copy number 8: 388; copy number 9: 202; copy number 10: 11; copy number 11: 71; copy number 13: 7; copy number 14: 17; copy number 18: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A23N-01A-11D-A227-01): tumor purity 0.53, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,668 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,634,168–9,949,974, 82 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:116,514,534–121,580,524, 117 genes, copy number 7 (broad region; genes not listed).
- chr2:204,470,076–242,160,153, 747 genes, copy number 7 (broad region; genes not listed).
- chr4:39,761,000–39,977,956, 3 genes, copy number 9 (within-gene range 4–9): RN7SL558P, ZBTB12BP, PDS5A.
- chr5:31,639,131–32,110,932, 1 gene, copy number 8 (within-gene range 4–8): PDZD2.
- chr5:31,820,564–32,791,724, 23 genes, copy number 8 (within-gene range 4–8): RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3.
- chr5:50,396,192–50,903,743, 7 genes, copy number 7–9: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3.
- chr5:170,232,447–178,232,802, 207 genes, copy number 8 (broad region; genes not listed).
- chr7:54,676,217–70,838,013, 370 genes, copy number 7–11 (broad region; genes not listed).
- chr8:13,536,029–13,584,533, 3 genes, copy number 7: RNA5SP255, C8orf48, AC022832.1.
- chr8:41,426,655–42,332,460, 28 genes, copy number 10–18 (within-gene range 3–18): SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB.
- chr19:27,638,483–31,655,461, 80 genes, copy number 11–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 800. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
